Somatic mutation profile of tumor specimen MMRF_1164_1_BM_CD138pos (aliquot MMRF_1164_1_BM_CD138pos_T2_KAS5U_L02450) from MMRF case MMRF_1164, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 70.2 years (25,632 days).
Specimen MMRF_1164_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c58327e0-3a1f-455d-9f6a-f270ca7e7b95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1164_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1164_1_PB_Whole_C3_KAS5U_L02461; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/99058254-e790-4c0a-ac41-0a085398414d

The open-access MAF lists 183 somatic variants for this specimen: 64 protein-altering or splice-affecting, 24 silent, 95 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 62, Missense Mutation 56, Silent 24, Intron 20, 5'UTR 4, RNA 4, 3'Flank 4, Nonsense Mutation 3, Splice Region 2, Frame Shift Del 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB5 | c.1423G>A p.G475R (on ENST00000404938 / NM_001163941.2; = p.G30R on NM_178559.6) | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs560868353, COSV99328210; called by muse, mutect2
- ADAMTSL2 | c.511T>G p.C171G | Missense Mutation (SNP) | VAF 23/218 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM113728; called by muse, mutect2, varscan2
- C9orf57 | c.415G>A p.V139I (on ENST00000377024 / NM_001371610.1; = p.V117I on NM_001128618.2) | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.007); catalogued as rs377108402, COSV65462514; called by muse, mutect2, varscan2
- CA7 | c.200C>G p.S67C | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58157195; called by muse, mutect2, varscan2
- CARD18 | c.171G>C p.L57F | Missense Mutation (SNP) | VAF 36/392 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs1213752009; called by muse, mutect2
- CNOT9 | c.260C>T p.S87F | Missense Mutation (SNP) | VAF 10/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55299607; called by muse, mutect2
- DSCAML1 | c.2617C>T p.R873W (on ENST00000321322; = p.R813W on NM_020693.4) | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs150629545; called by muse, mutect2
- FAM184A | c.3110C>A p.T1037N | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV58854629; called by muse, mutect2, varscan2
- GOLM2 | c.293G>A p.R98K | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs747082945; called by muse, mutect2
- IGKV4-1 | c.199G>C p.G67R | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as rs536959831; called by muse, varscan2
- IGLV3-1 | c.310T>C p.Y104H | Missense Mutation (SNP) | VAF 60/124 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs180853064; called by muse, mutect2, varscan2
- IL15 | c.-97T>G | Splice Region (SNP) | VAF 24/200 reads (12%) | catalogued as rs1296176593; called by muse, mutect2, varscan2
- INTU | c.751A>G p.I251V | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.094); catalogued as rs768291147; called by muse, mutect2, varscan2
- KAT6B | c.4735G>A p.D1579N | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.118); catalogued as COSV54743775; called by muse, mutect2, varscan2
- LAMB4 | c.2533C>T p.R845C | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs376458283; called by muse, mutect2, varscan2
- LOXHD1 | c.4555G>A p.A1519T | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as rs899694804, COSV56062764; called by muse, mutect2, varscan2
- NUBPL | c.58G>A p.G20R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs755396987; called by muse, mutect2, varscan2
- PCDHA6 | c.1033G>T p.D345Y | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100972056; called by muse, mutect2
- PLPPR5 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs900156255, COSV99587442; called by muse, mutect2
- SGCB | c.752C>T p.A251V | Missense Mutation (SNP) | VAF 21/224 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); catalogued as rs146111013; ClinVar: uncertain significance; called by muse, mutect2
- SLC5A7 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV50891645; called by muse, mutect2, varscan2
- SPAG17 | c.5599G>C p.D1867H | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV100307756; called by muse, mutect2, varscan2
- TMEM225B | c.62C>T p.T21I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs895072823; called by muse, mutect2, varscan2
- TRIM14 | c.1233G>A p.M411I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.995); catalogued as rs755682455; called by muse, varscan2
- TSC22D2 | c.463C>G p.P155A | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV62622416; called by muse, mutect2
- VPS4B | c.94C>T p.Q32* | Nonsense Mutation (SNP) | VAF 7/154 reads (5%) | catalogued as COSV99031904; called by muse, mutect2
- VSIG10L | c.1957G>A p.V653M | Missense Mutation (SNP) | VAF 9/226 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1039386421; called by muse, mutect2
- VWDE | c.592C>A p.L198M | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99281621; called by muse, mutect2
- ZBED1 | c.380C>A p.T127K | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58134616; called by muse, mutect2, varscan2
- ZNF587 | c.911C>G p.S304C | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs1372677118, COSV100299651; called by muse, mutect2
- ADGRL2 | c.595A>C p.T199P | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- DNAH9 | c.9104G>C p.R3035P | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DROSHA | c.2239A>G p.T747A | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- E2F7 | c.437G>A p.S146N | Missense Mutation (SNP) | VAF 25/124 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FANCM | c.5018C>A p.S1673* | Nonsense Mutation (SNP) | VAF 30/40 reads (75%) | called by muse, mutect2, varscan2
- FRMPD4 | c.3788A>G p.E1263G | Missense Mutation (SNP) | VAF 7/139 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.606); called by muse, mutect2
- FSIP2 | c.17684A>G p.K5895R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- GATA4 | c.703C>T p.H235Y | Missense Mutation (SNP) | VAF 25/212 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- HOXD12 | c.152G>T p.W51L | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- IGKV4-1 | c.170_179del p.N57Ifs*? | Frame Shift Del (DEL) | VAF 18/34 reads (53%) | called by pindel, varscan2
- MAGEB1 | c.460T>A p.S154T | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- MAP2 | c.4439C>G p.S1480C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- MSH3 | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MSH6 | c.3145T>C p.S1049P | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- MYCBP2 | c.9197C>T p.P3066L (on ENST00000357337; = p.P3104L on NM_015057.5) | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- NCOA2 | c.1987G>C p.D663H | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); called by muse, mutect2
- NECTIN3 | c.733A>G p.T245A | Missense Mutation (SNP) | VAF 73/193 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- NLRP5 | c.2655G>T p.K885N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR5K2 | c.899T>C p.V300A | Missense Mutation (SNP) | VAF 11/304 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2
- PIEZO2 | c.8176G>C p.E2726Q | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PIK3CD | c.1248C>G p.C416W | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PRR32 | c.166A>G p.R56G | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- RFT1 | c.1055A>G p.Q352R | Missense Mutation (SNP) | VAF 19/137 reads (14%) | SIFT tolerated (0.28); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ROBO2 | c.422_427del p.D141_V142del | In Frame Del (DEL) | VAF 12/28 reads (43%) | called by mutect2, pindel, varscan2
- RREB1 | c.897+2T>C p.X299_splice | Splice Site (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2
- SNX20 | c.46A>G p.I16V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYNE1 | c.16713C>T p.T5571= (on ENST00000367255 / NM_182961.4; = p.T5500= on NM_033071.3) | Splice Region (SNP) | VAF 23/60 reads (38%) | called by muse, mutect2, varscan2
- SYNE2 | c.15546G>C p.L5182F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- TSHZ2 | c.2573C>A p.A858D | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TST | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- WDFY4 | c.4321C>T p.L1441F | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.11); called by muse, varscan2
- WDFY4 | c.4330G>T p.A1444S | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.38); PolyPhen benign (0.02); called by muse, varscan2
- WDR72 | c.3263G>T p.R1088M | Missense Mutation (SNP) | VAF 31/258 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- XKR3 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- ADAMTSL1 | c.1779C>T p.D593= | Silent (SNP) | VAF 45/111 reads (41%) | catalogued as rs779246681; called by muse, mutect2, varscan2
- AMMECR1 | c.414C>T p.L138= | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- ARX | c.1491G>A p.A497= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as rs1021002740; called by muse, mutect2, varscan2
- CAPN9 | c.633G>A p.E211= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- CELSR1 | c.7143C>T p.S2381= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs369520213; called by muse, mutect2, varscan2
- CHST3 | c.540C>T p.N180= | Silent (SNP) | VAF 9/72 reads (13%) | catalogued as rs748812857, COSV64150382; called by muse, mutect2, varscan2
- ESRP2 | c.384C>T p.L128= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV52174527; called by muse, mutect2, varscan2
- FANCA | c.3216G>A p.Q1072= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs753298211; called by mutect2, varscan2
- GPX2 | c.321G>A p.V107= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- HIPK3 | c.126G>A p.R42= | Silent (SNP) | VAF 72/213 reads (34%) | called by muse, mutect2, varscan2
- HSP90AB1 | c.405T>C p.S135= | Silent (SNP) | VAF 73/170 reads (43%) | called by muse, mutect2, varscan2
- IGHV1-69D | c.282C>T p.S94= | Silent (SNP) | VAF 61/76 reads (80%) | called by muse, varscan2
- LHX1 | c.270C>A p.T90= | Silent (SNP) | VAF 16/158 reads (10%) | called by muse, mutect2
- MAST4 | c.5274C>T p.L1758= (on ENST00000403625 / NM_001164664.2; = p.L1569= on NM_015183.3) | Silent (SNP) | VAF 8/100 reads (8%) | catalogued as COSV55145957; called by muse, mutect2
- MYO1B | c.1395C>T p.L465= | Silent (SNP) | VAF 13/140 reads (9%) | called by muse, mutect2
- NPL | c.472T>C p.L158= | Silent (SNP) | VAF 19/61 reads (31%) | called by muse, mutect2, varscan2
- OGT | c.1809G>T p.V603= | Silent (SNP) | VAF 14/113 reads (12%) | called by muse, mutect2, varscan2
- OR4C16 | c.669G>A p.L223= | Silent (SNP) | VAF 12/148 reads (8%) | catalogued as COSV58941190; called by muse, mutect2
- PROS1 | c.831A>G p.Q277= | Silent (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- PXK | c.939G>A p.L313= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs1427118124; called by muse, mutect2, varscan2
- RAB23 | c.624C>T p.T208= | Silent (SNP) | VAF 10/80 reads (13%) | called by muse, mutect2, varscan2
- WDFY4 | c.4329G>T p.V1443= | Silent (SNP) | VAF 36/102 reads (35%) | called by muse, varscan2
- ZNF467 | c.855G>A p.T285= | Silent (SNP) | VAF 3/52 reads (6%) | catalogued as rs1433440699, COSV57373230; called by muse, mutect2
- ZNF516 | c.1131G>A p.S377= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs1409471328; called by muse, mutect2, varscan2
- AC112695.1 | n.369G>A | RNA (SNP) | VAF 13/25 reads (52%) | catalogued as rs946481305; called by muse, mutect2, varscan2
- AC244394.2 | n.838G>A | RNA (SNP) | VAF 16/170 reads (9%) | called by muse, mutect2
- AFG1L | c.*1878A>T | 3'UTR (SNP) | VAF 6/71 reads (8%) | catalogued as rs976803153; called by muse, mutect2
- AGO2 | c.1269+42T>A | Intron (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2, varscan2
- AIFM1 | c.968-465G>C | Intron (SNP) | VAF 59/270 reads (22%) | called by muse, mutect2, varscan2
- ALDH5A1 | c.*3425T>C | 3'UTR (SNP) | VAF 13/94 reads (14%) | called by muse, mutect2, varscan2
- AMER2 | c.*7362T>A | 3'UTR (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- AMOT | c.*3543C>T | 3'UTR (SNP) | VAF 7/72 reads (10%) | catalogued as rs1259495737; called by muse, mutect2
- ANO10 | c.*219C>G | 3'UTR (SNP) | VAF 3/46 reads (7%) | called by muse, mutect2
- ARFGEF3 | c.*7077C>A | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- ARHGEF10L | c.*105C>G | 3'UTR (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- ATP13A2 | c.348-15C>T | Intron (SNP) | VAF 9/60 reads (15%) | called by muse, mutect2, varscan2
- ATP1B4 | c.*327C>A | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- ATP1B4 | c.*597A>G | 3'UTR (SNP) | VAF 12/32 reads (38%) | called by muse, mutect2, varscan2
- BET1L | c.19+131C>T | Intron (SNP) | VAF 5/18 reads (28%) | called by muse, mutect2, varscan2
- BHLHE40 | c.*353C>T | 3'UTR (SNP) | VAF 8/145 reads (6%) | called by muse, mutect2
- BRSK2 | c.414-32G>T | Intron (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- BSND | c.*2067A>T | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- C2orf69 | c.*946T>C | 3'UTR (SNP) | VAF 28/76 reads (37%) | called by muse, mutect2, varscan2
- CCDC102B | c.*81G>T | 3'UTR (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- CD200R1L | c.46+4347G>C | Intron (SNP) | VAF 5/35 reads (14%) | called by muse, mutect2
- CEP78 | c.*2035G>T | 3'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- CHST11 | c.-36C>T | 5'UTR (SNP) | VAF 6/61 reads (10%) | called by muse, mutect2, varscan2
- CHST13 | c.*350A>G | 3'UTR (SNP) | VAF 32/92 reads (35%) | called by muse, mutect2, varscan2
- CREB5 | c.*6114G>A | 3'UTR (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2, varscan2
- DCX | c.*4343C>T | 3'UTR (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
- DKK2 | c.*1098G>C | 3'UTR (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- DSC2 | c.*90T>C | 3'UTR (SNP) | VAF 14/106 reads (13%) | called by muse, mutect2, varscan2
- EIF1 | c.*1481G>A | 3'UTR (SNP) | VAF 29/67 reads (43%) | called by muse, mutect2, varscan2
- ELL3 | c.168+101C>T | Intron (SNP) | VAF 9/163 reads (6%) | called by muse, mutect2
- ESS2 | c.135+25C>T | Intron (SNP) | VAF 12/126 reads (10%) | catalogued as rs766259698; called by muse, mutect2
- FAM98A | c.*828C>T | 3'UTR (SNP) | VAF 7/65 reads (11%) | catalogued as rs145203305; called by muse, mutect2, varscan2
- FGD4 | c.*3191_*3192del | 3'UTR (DEL) | VAF 13/98 reads (13%) | called by mutect2, pindel, varscan2
- FGF14 | c.*99A>T | 3'UTR (SNP) | VAF 19/112 reads (17%) | called by muse, mutect2, varscan2
- FOSB | c.*5T>C | 3'UTR (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- GRIN1 | c.2589+601G>A | Intron (SNP) | VAF 26/160 reads (16%) | catalogued as rs1182228190, COSV104407991; called by muse, mutect2, varscan2
- HOXA13 | c.*675T>A | 3'UTR (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2, varscan2
- ICA1L | chr2:202777513 G>A | 3'Flank (SNP) | VAF 6/70 reads (9%) | called by muse, mutect2
- IKZF2 | c.*1766A>G | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- ISG20 | c.*148C>G | 3'UTR (SNP) | VAF 13/92 reads (14%) | called by muse, mutect2, varscan2
- ITGB6 | c.*1294C>G | 3'UTR (SNP) | VAF 7/63 reads (11%) | called by muse, mutect2, varscan2
- KCNJ18 | c.*394G>A | 3'UTR (SNP) | VAF 6/31 reads (19%) | catalogued as rs1229623025; called by muse, mutect2
- KCNU1 | c.2010-16352G>A | Intron (SNP) | VAF 5/40 reads (13%) | called by muse, mutect2
- KCTD7 | c.*244_*245del | 3'UTR (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel, varscan2
- KIAA0586 | c.-39+47G>A | Intron (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2
- LATS1 | c.*455G>C | 3'UTR (SNP) | VAF 10/143 reads (7%) | called by muse, mutect2
- LRRC40 | c.*596A>T | 3'UTR (SNP) | VAF 13/112 reads (12%) | called by muse, mutect2, varscan2
- MBLAC2 | c.*1003G>A | 3'UTR (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- MCIDAS | c.*94G>A | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- MIR1263 | n.51A>T | RNA (SNP) | VAF 9/78 reads (12%) | called by muse, mutect2, varscan2
- MIR507 | n.53A>C | RNA (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2, varscan2
- MIR7162 | chr10:30365365 C>T | 3'Flank (SNP) | VAF 12/188 reads (6%) | catalogued as rs1382763581; called by muse, mutect2
- MRS2 | c.*1861C>G | 3'UTR (SNP) | VAF 15/30 reads (50%) | called by muse, mutect2, varscan2
- MTRF1 | chr13:41216870 del C | 3'Flank (DEL) | VAF 22/86 reads (26%) | called by mutect2, pindel, varscan2
- MYOZ3 | c.*2000G>C | 3'UTR (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- NALCN | c.*276T>A | 3'UTR (SNP) | VAF 11/40 reads (28%) | called by muse, mutect2, varscan2
- NDUFA6 | c.*647T>C | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- NIPAL4 | c.*987G>C | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- NLGN1 | c.*3245G>T | 3'UTR (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- NNMT | c.-117G>A | 5'UTR (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- NRN1 | c.*289T>A | 3'UTR (SNP) | VAF 11/33 reads (33%) | catalogued as rs561988183; called by muse, mutect2, varscan2
- OVCH1 | c.892+626G>A | Intron (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- PAPPA2 | c.*1129A>T | 3'UTR (SNP) | VAF 20/53 reads (38%) | called by muse, mutect2, varscan2
- PAQR5 | c.512+1773G>A | Intron (SNP) | VAF 8/53 reads (15%) | catalogued as rs896370674; called by muse, mutect2, varscan2
- PCDH11X | c.*2603G>T | 3'UTR (SNP) | VAF 24/238 reads (10%) | called by muse, mutect2, varscan2
- PCDH18 | c.*799C>T | 3'UTR (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- PDLIM5 | c.*2958C>G | 3'UTR (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2
- PDZD7 | c.719+99G>A | Intron (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2
- PLAA | c.*17C>T | 3'UTR (SNP) | VAF 24/334 reads (7%) | catalogued as rs373253466; called by muse, mutect2
- PLAAT5 | chr11:63462900 A>C | 3'Flank (SNP) | VAF 9/97 reads (9%) | called by muse, mutect2
- PLAGL2 | c.*902A>C | 3'UTR (SNP) | VAF 37/81 reads (46%) | called by muse, mutect2, varscan2
- REG1B | c.64+44C>T | Intron (SNP) | VAF 20/152 reads (13%) | called by muse, mutect2, varscan2
- RHNO1 | c.-84-54G>A | Intron (SNP) | VAF 5/38 reads (13%) | called by muse, mutect2, varscan2
- RNF38 | c.*3203G>C | 3'UTR (SNP) | VAF 5/81 reads (6%) | called by muse, mutect2
- RNU6-713P | chr12:40557866 C>A | 5'Flank (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- RRM2 | c.*1709G>A | 3'UTR (SNP) | VAF 36/83 reads (43%) | catalogued as rs1034987931; called by muse, mutect2, varscan2
- SEMA3E | c.*2656A>G | 3'UTR (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
- SFI1 | c.2997-197G>C | Intron (SNP) | VAF 17/163 reads (10%) | called by muse, mutect2
- SH3GLB1 | c.-43C>T | 5'UTR (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100990750; called by muse, mutect2
- SH3KBP1 | c.*234G>A | 3'UTR (SNP) | VAF 31/71 reads (44%) | called by muse, mutect2, varscan2
- SIRT1 | c.*557G>T | 3'UTR (SNP) | VAF 9/73 reads (12%) | called by muse, mutect2, varscan2
- SMIM30 | c.*445T>C | 3'UTR (SNP) | VAF 8/128 reads (6%) | called by muse, mutect2
- SPATA13 | c.-190A>G | 5'UTR (SNP) | VAF 9/70 reads (13%) | called by muse, mutect2, varscan2
- SPOCK2 | c.*778C>T | 3'UTR (SNP) | VAF 10/129 reads (8%) | catalogued as rs1051192264; called by muse, mutect2
- SYF2 | c.*70T>C | 3'UTR (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- TAF1L | c.*166C>G | 3'UTR (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- TOP1 | c.*388T>C | 3'UTR (SNP) | VAF 24/358 reads (7%) | called by muse, mutect2
- TRAF3 | c.*288G>A | 3'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as rs1443134086; called by muse, mutect2
- TRPV3 | c.*1180G>T | 3'UTR (SNP) | VAF 33/82 reads (40%) | called by muse, mutect2, varscan2
- XKR6 | c.764+91535C>A | Intron (SNP) | VAF 6/78 reads (8%) | called by muse, mutect2
- XPO7 | c.2944-98del | Intron (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- XRN1 | c.*939_*941del | 3'UTR (DEL) | VAF 16/101 reads (16%) | catalogued as rs1203974168; called by pindel, varscan2
- ZDHHC7 | c.*832T>A | 3'UTR (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- ZNF382 | c.140-141C>T | Intron (SNP) | VAF 8/64 reads (13%) | called by muse, varscan2
- ZNF700 | c.*438C>A | 3'UTR (SNP) | VAF 9/128 reads (7%) | called by muse, mutect2
